Somatic mutation profile of tumor specimen TCGA-DI-A2QT-01A (aliquot TCGA-DI-A2QT-01A-12D-A19Y-09) from TCGA case TCGA-DI-A2QT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.6 years (18,835 days).
Specimen TCGA-DI-A2QT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f325b0d0-042b-4cb5-8671-155933453cd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DI-A2QT-10A (Blood Derived Normal), aliquot TCGA-DI-A2QT-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7b8d359-d982-4ad6-8532-3e2bacee7a87

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 3, In Frame Del 1, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1634A>G p.Y545C (on ENST00000281708 / NM_001349798.2; = p.Y465C on NM_018315.5) | Missense Mutation (SNP) | VAF 53/60 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560758208, COSV55890892, COSV55908001, COSV55914345; called by muse, mutect2, varscan2
- TP53 | c.783-29_783del p.X261_splice | Splice Site (DEL) | VAF 12/31 reads (39%) | hotspot (GDC flag); called by mutect2, varscan2
- ABCC2 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100965572; called by muse, mutect2, varscan2
- BCLAF1 | c.1959G>T p.R653S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99219346; called by mutect2, varscan2
- CDH2 | c.2290G>T p.D764Y | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52285943, COSV99295862; called by muse, mutect2, varscan2
- DHX34 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100169289; called by muse, mutect2
- ELAPOR1 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as rs536963258, COSV100884407; called by muse, mutect2, varscan2
- ENAM | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV101252946; called by muse, mutect2, varscan2
- KMT2D | c.12218C>G p.S4073* | Nonsense Mutation (SNP) | VAF 21/28 reads (75%) | catalogued as COSV99978077; called by muse, mutect2, varscan2
- MNDA | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751266784, COSV63740840; called by muse, mutect2, varscan2
- MORN1 | c.744G>T p.K248N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV101047357; called by muse, mutect2, varscan2
- NR2C1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as rs746233609, COSV58009121; called by muse, mutect2, varscan2
- PODXL2 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs749040344, COSV61065348; called by muse, mutect2, varscan2
- STAT5A | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61805694; called by muse, mutect2, varscan2
- USP38 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100189113; called by muse, mutect2, varscan2
- VIT | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV101007188; called by muse, mutect2, varscan2
- VPS13A | c.8884C>T p.R2962C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767557525, COSV100652239; called by muse, mutect2, varscan2
- ZFHX3 | c.8189T>G p.I2730S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99195446; called by muse, mutect2, varscan2
- CTR9 | c.118_119dup p.Q40Hfs*23 | Frame Shift Ins (INS) | VAF 13/23 reads (57%) | called by mutect2, varscan2
- DDX52 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 10/318 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.056); called by muse, mutect2
- NPHS1 | c.3607C>A p.L1203I | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2
- PIK3CA | c.25_54del p.E9_P18del | In Frame Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- MAP7D2 | c.1774T>C p.L592= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV101107189; called by muse, mutect2
- RELN | c.10293C>T p.R3431= | Silent (SNP) | VAF 45/86 reads (52%) | catalogued as COSV100632632; called by muse, mutect2, varscan2
- WASHC4 | c.3193C>A p.R1065= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100162174; called by mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-51592G>T | Intron (SNP) | VAF 9/50 reads (18%) | catalogued as rs775675262, COSV67443294; called by muse, mutect2, varscan2
